EXCEPTIONAL_RESPONDERS case ER-ABU7 — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8d37af13-d632-44ba-82fe-452d2368626f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age: 90 years or older (exact value withheld by GDC); Vital status: Dead; Days to death: 47 days; Year of death: 2012.

Diagnoses (1)
1. Melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin of upper limb and shoulder; Site of resection or biopsy: Skin of upper limb and shoulder; Classification of tumor: primary; Age at diagnosis: 90 years or older (exact value withheld by GDC); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic stage: Stage IIIA; Prior malignancy: no; Days to last follow up: 47 days; Days to best overall response: 47 days; Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Ipilimumab; Days to treatment start: 47 days; Days to treatment end: 47 days.

Follow-up (1 entry)
- Days to follow up: 47 days; Disease response: Clinical Progression; Progression or recurrence: Yes; Days to progression: 47 days; Days to recurrence: 47 days; Days progression-free: 47 days.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ABU7-TMM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE.
  Slide ER-ABU7-TMM1-A-1-0-S1: Section location: Top; Percent tumor cells: 10; Percent tumor nuclei: 20; Percent normal cells: 90; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 80.
- Sample ER-ABU7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide ER-ABU7-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 5; Percent tumor nuclei: 40; Percent normal cells: 95; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
